Somatic mutation profile of tumor specimen 0DGQBE from CCDI case PBBTTZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.3 years (475 days).
Specimen 0DGQBE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 771675ec-e67d-4de3-8b3b-6d9bce43536a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGQAJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83ab8f53-6831-4537-a5ad-4b8f253e0d66

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SNED1 | c.2023C>T p.R675W | Missense Mutation (SNP) | VAF 239/555 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.528); catalogued as rs769639798; called by muse, mutect2, varscan2
- WDR62 | c.2490C>T p.N830= | Silent (SNP) | VAF 71/391 reads (18%) | catalogued as rs587784547, COSV54339124; ClinVar: uncertain significance; called by muse, mutect2, varscan2
